Somatic mutation profile of tumor specimen TCGA-AR-A0TV-01A (aliquot TCGA-AR-A0TV-01A-21D-A099-09) from TCGA case TCGA-AR-A0TV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.5 years (24,279 days).
Specimen TCGA-AR-A0TV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34d2b347-d19f-42cc-8776-157a2dd6ed07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TV-10A (Blood Derived Normal), aliquot TCGA-AR-A0TV-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f23b8be-ebda-42d7-915b-af047f5bd420

The open-access MAF lists 69 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 11, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, Intron 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 138/192 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.3472T>G p.S1158A | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99273605; called by muse, mutect2, varscan2
- ALPI | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs377199045, COSV99786057; called by muse, mutect2, varscan2
- AP1S3 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV100525350, COSV57510817; called by muse, mutect2, varscan2
- ARID4A | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100794492, COSV62164720; called by muse, mutect2, varscan2
- BRINP3 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100819138, COSV99054917; called by muse, mutect2, varscan2
- CDH10 | c.109T>A p.L37I | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100052371; called by muse, mutect2, varscan2
- CFAP44 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.47); catalogued as COSV99870104; called by muse, mutect2, varscan2
- CLCN3 | c.2309T>G p.I770S | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV100641781; called by muse, mutect2, varscan2
- DCAF4L2 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1245145166, COSV60480306; called by muse, mutect2, varscan2
- DEAF1 | c.1542delinsAT p.C515Lfs*43 | Frame Shift Ins (INS) | VAF 27/79 reads (34%) | catalogued as COSV58608511; called by mutect2*, pindel, varscan2*
- DPY19L4 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 102/1284 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.433); catalogued as COSV101363400, COSV68962661; called by muse, mutect2
- DUSP22 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs757843915, COSV60524977, COSV60532953; called by muse, mutect2
- EFHC2 | c.1609A>T p.N537Y | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV101375504; called by muse, mutect2, varscan2
- EGFR | c.1577G>C p.C526S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99293406; called by muse, mutect2
- EIF4A2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100125584; called by muse, mutect2, varscan2
- EPB41L4A | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs969570026, COSV99813774; called by muse, mutect2, varscan2
- FAT3 | c.11529C>G p.N3843K | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99968222; called by muse, mutect2, varscan2
- GATAD2B | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100897946; called by muse, mutect2, varscan2
- GJA5 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV54783471; called by muse, mutect2, varscan2
- HEATR6 | c.2708C>G p.S903C | Missense Mutation (SNP) | VAF 263/341 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1205688831, COSV99482482; called by muse, mutect2, varscan2
- HEPHL1 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as COSV100244138; called by muse, mutect2, varscan2
- KHDRBS2 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV99835791; called by muse, mutect2, varscan2
- KIF18A | c.2674A>G p.I892V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV99588942; called by muse, mutect2, varscan2
- KIF4A | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); catalogued as COSV100978669; called by muse, mutect2, varscan2
- MAEL | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100901907; called by muse, mutect2, varscan2
- MEF2C | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.538); catalogued as COSV100425832; called by muse, mutect2, varscan2
- MYH7B | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs750330627, COSV99483072; called by muse, mutect2, varscan2
- MYH7B | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53424244; called by muse, mutect2, varscan2
- NANS | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs1209933662, COSV99271345; called by muse, mutect2, varscan2
- NBEAL1 | c.5468A>G p.H1823R | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1192369323, COSV101495746; called by muse, mutect2, varscan2
- NCOR1 | c.3644A>G p.K1215R | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1211435262, COSV99251114; called by muse, mutect2, varscan2
- NEB | c.14689C>A p.P4897T | Missense Mutation (SNP) | VAF 185/394 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425716; called by muse, mutect2, varscan2
- NECAB1 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101341139; called by muse, mutect2, varscan2
- OPRK1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200672427, COSV55568081; called by muse, mutect2, varscan2
- OR10H2 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs368469319, COSV99045397; called by muse, mutect2, varscan2
- PCARE | c.2888C>T p.S963F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV100527728; called by muse, mutect2, varscan2
- PCDH1 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 48/146 reads (33%) | catalogued as COSV99746607; called by muse, mutect2, varscan2
- POU6F1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs759527012, COSV61327910; called by muse, mutect2, varscan2
- PTPRG | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55628279, COSV99876138; called by muse, mutect2, varscan2
- RAPH1 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.17); catalogued as rs747909587, COSV99864135; called by muse, mutect2, varscan2
- SLC4A5 | c.2957del p.L986Rfs*12 | Frame Shift Del (DEL) | VAF 54/187 reads (29%) | catalogued as COSV100697436; called by mutect2, pindel, varscan2
- SMC1B | c.572del p.N191Ifs*2 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as rs748761052; called by mutect2, varscan2
- SYBU | c.1250A>G p.E417G (on ENST00000276646 / NM_001099754.2; = p.E416G on NM_017786.6) | Missense Mutation (SNP) | VAF 47/592 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.74); catalogued as COSV99406458; called by muse, mutect2
- SYN1 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99927809; called by muse, mutect2, varscan2
- TDRD10 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 81/200 reads (41%) | catalogued as rs759988293, COSV52725948; called by muse, mutect2, varscan2
- TGM1 | c.1069G>C p.G357R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99253141; called by muse, mutect2, varscan2
- ULK2 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100860918; called by muse, mutect2, varscan2
- ZBTB17 | c.590T>G p.L197R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.125); catalogued as COSV100999044; called by muse, mutect2, varscan2
- ZNF48 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as rs1421054905, COSV100198187; called by muse, mutect2, varscan2
- ZNF713 | c.56T>G p.L19R (on ENST00000633730 / NM_001366796.2; = p.L32R on NM_182633.3) | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV101289516; called by muse, mutect2, varscan2
- DEAF1 | c.1543dup p.C515Lfs*43 | Frame Shift Ins (INS) | VAF 40/67 reads (60%) | called by mutect2, varscan2
- OR10Z1 | c.851del p.L284Pfs*9 | Frame Shift Del (DEL) | VAF 54/176 reads (31%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.809A>C p.K270T | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBP1 | c.1569_1571del p.L523del | In Frame Del (DEL) | VAF 53/160 reads (33%) | called by mutect2, pindel, varscan2
- ABCG4 | c.915G>A p.P305= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as rs201199426, COSV56642249; called by muse, mutect2, varscan2
- CLEC4G | c.687C>T p.R229= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV61003824; called by muse, mutect2, varscan2
- FBXO38 | c.1182A>T p.A394= | Silent (SNP) | VAF 42/171 reads (25%) | catalogued as COSV99693722; called by muse, mutect2, varscan2
- GTPBP6 | c.954C>T p.A318= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as rs764275252, COSV100397798; called by muse, mutect2, varscan2
- KIAA1109 | c.8862T>A p.V2954= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV99160112, COSV99167904; called by muse, mutect2, varscan2
- MAX | c.333G>A p.L111= | Silent (SNP) | VAF 72/129 reads (56%) | catalogued as COSV52416672; called by muse, mutect2, varscan2
- SLIT1 | c.1569G>A p.V523= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99822024; called by muse, mutect2, varscan2
- STXBP2 | c.1407C>G p.T469= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99657277; called by muse, mutect2, varscan2
- TNR | c.930G>A p.G310= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV99690621; called by muse, mutect2, varscan2
- TUBB | c.1131C>T p.L377= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100013421; called by muse, mutect2, varscan2
- ZC2HC1A | c.363A>G p.Q121= | Silent (SNP) | VAF 26/228 reads (11%) | catalogued as rs756139685, COSV99804284; called by muse, mutect2, varscan2
- LEPR | c.2674-3035C>T | Intron (SNP) | VAF 18/48 reads (38%) | catalogued as rs762314477, COSV62750563; called by muse, mutect2, varscan2
- MIR519A2 | n.48G>T | RNA (SNP) | VAF 47/317 reads (15%) | called by muse, mutect2, varscan2
- RN7SL262P | chrX:49157328 G>A | 3'Flank (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
